Somatic mutation profile of tumor specimen MP2PRT-PASRBW-TMP1-A (aliquot MP2PRT-PASRBW-TMP1-A-1-0-D-A81X-36) from MP2PRT case MP2PRT-PASRBW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.1 years (784 days).
Specimen MP2PRT-PASRBW-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d840a752-92af-48a6-a72a-5ad3fcf61458.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASRBW-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASRBW-NB1-A-1-0-D-A81X-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/edae448e-05f4-480c-9195-3c1fccaf5264

The open-access MAF lists 11 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Intron 1, Frame Shift Ins 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM32 | c.1071G>C p.K357N | Missense Mutation (SNP) | VAF 80/229 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101165387; called by muse, mutect2, varscan2
- CNGB1 | c.2455G>A p.G819S | Missense Mutation (SNP) | VAF 109/279 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1311445618; called by muse, mutect2, varscan2
- CXorf65 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 97/243 reads (40%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as rs963337813, COSV52147220; called by muse, mutect2, varscan2
- CCDC88C | c.2808G>C p.E936D | Missense Mutation (SNP) | VAF 133/317 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- MCF2L | c.2933G>A p.R978K (on ENST00000375608; = p.R946K on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 96/263 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MRC1 | c.568G>A p.G190R | Missense Mutation (SNP) | VAF 160/420 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PALLD | c.217dup p.A73Gfs*5 | Frame Shift Ins (INS) | VAF 163/442 reads (37%) | called by mutect2, pindel, varscan2
- TASP1 | c.1250G>C p.S417T | Missense Mutation (SNP) | VAF 88/238 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.06); called by muse, varscan2
- ZNF679 | c.609G>C p.Q203H | Missense Mutation (SNP) | VAF 95/311 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CYP24A1 | c.66G>A p.R22= | Silent (SNP) | VAF 91/518 reads (18%) | called by muse, mutect2, varscan2
- MASP1 | c.1303+5731C>T | Intron (SNP) | VAF 70/374 reads (19%) | catalogued as rs144758799; called by muse, mutect2, varscan2
